Somatic mutation profile of tumor specimen TCGA-GU-A766-01A (aliquot TCGA-GU-A766-01A-11D-A32B-08) from TCGA case TCGA-GU-A766, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 62.4 years (22,774 days).
Specimen TCGA-GU-A766-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) affd2da2-8d52-4213-b303-99a09084e93c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GU-A766-10A (Blood Derived Normal), aliquot TCGA-GU-A766-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe051a25-fcf1-4a13-9a33-13fb5f148515

The open-access MAF lists 210 somatic variants for this specimen: 153 protein-altering or splice-affecting, 52 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 52, Nonsense Mutation 16, Intron 3, Frame Shift Del 3, Splice Region 1, Splice Site 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSP | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 48/265 reads (18%) | catalogued as rs397516943, BM1344445, COSV101131255, COSV65793658; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 84/272 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 14/105 reads (13%) | catalogued as rs1555034779, COSV100627800; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RP1 | c.2029C>T p.R677* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as rs104894082, CD992276, CM991103, COSV55128917; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAMBP | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs766580482, COSV59898119; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as rs879253911, CM941328, COSV52694461, COSV52816009, COSV53014483, COSV53470757; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.348); catalogued as COSV62931930; called by muse, mutect2, varscan2
- ABCA6 | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52643368; called by muse, mutect2
- ACTL8 | c.377C>G p.S126W | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64860166, COSV64862429; called by muse, mutect2, varscan2
- ACTRT1 | c.827C>A p.S276* | Nonsense Mutation (SNP) | VAF 44/94 reads (47%) | catalogued as COSV100947569; called by muse, mutect2, varscan2
- AFF3 | c.3129G>A p.M1043I | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV57854880; called by muse, mutect2, varscan2
- ANAPC5 | c.397G>A p.G133S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99946139; called by muse, mutect2
- ARHGEF19 | c.696G>A p.G232= | Splice Region (SNP) | VAF 10/48 reads (21%) | catalogued as COSV54616146; called by muse, mutect2, varscan2
- ARID1A | c.1534C>T p.Q512* | Nonsense Mutation (SNP) | VAF 89/295 reads (30%) | catalogued as COSV61374734; called by muse, mutect2, varscan2
- ASRGL1 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs200906420, COSV57126022; called by muse, mutect2, varscan2
- ATP8A2 | c.1984G>C p.E662Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.528); catalogued as COSV54970737; called by muse, mutect2, varscan2
- ATR | c.3439G>A p.D1147N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.31); catalogued as COSV100638139; called by muse, mutect2
- C3orf20 | c.1090C>G p.Q364E | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.397); catalogued as COSV53787144, COSV53788331; called by muse, mutect2, varscan2
- CACNA1E | c.5801G>A p.G1934E | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV62390443; called by muse, mutect2
- CANX | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56006253; called by muse, mutect2, varscan2
- CCBE1 | c.1088C>G p.S363C | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67950113, COSV67951199; called by muse, mutect2, varscan2
- CCDC144A | c.3610G>C p.E1204Q | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.44); catalogued as COSV60700880, COSV60701178; called by muse, mutect2, varscan2
- CCDC77 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53474750; called by muse, mutect2, varscan2
- CDH23 | c.5899G>C p.E1967Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.907); catalogued as COSV56482848; called by muse, mutect2, varscan2
- CIAO2A | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55539069; called by muse, mutect2, varscan2
- CKS2 | c.150G>C p.Q50H | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV58686782; called by muse, mutect2, varscan2
- CLIP1 | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100211600; called by muse, mutect2, varscan2
- CMTR1 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV65091484; called by muse, mutect2, varscan2
- COL6A2 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); catalogued as rs371383704, COSV100153416; called by muse, mutect2
- CSNK1G3 | c.267C>G p.F89L | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.598); catalogued as COSV62053694, COSV62056338; called by muse, mutect2, varscan2
- CUL9 | c.6270C>G p.H2090Q | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV52732884; called by muse, mutect2, varscan2
- DDX6 | c.166C>G p.Q56E | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); catalogued as rs1267029171, COSV50590819; called by muse, mutect2, varscan2
- DLG5 | c.4423G>A p.E1475K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.801); catalogued as rs1460439717, COSV64949337; called by muse, mutect2, varscan2
- DNAJA3 | c.288G>C p.Q96H | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52163588; called by muse, mutect2, varscan2
- DPP8 | c.2352G>C p.W784C (on ENST00000341861 / NM_001320875.2; = p.W668C on NM_017743.6) | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55682126, COSV55683701; called by muse, varscan2
- DSP | c.6065C>G p.S2022C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.788); catalogued as COSV65794768; called by muse, mutect2, varscan2
- DTWD1 | c.350A>C p.E117A | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV52072574; called by muse, mutect2
- DTX3 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 39/306 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.019); catalogued as COSV54089662; called by muse, mutect2, varscan2
- EDRF1 | c.1942G>A p.E648K (on ENST00000356792 / NM_001202438.2; = p.E614K on NM_015608.2) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as rs144071063; called by muse, mutect2, varscan2
- EIF3M | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.709); catalogued as COSV60073384; called by muse, mutect2, varscan2
- ELMO1 | c.2173G>C p.D725H | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV60318839; called by muse, mutect2, varscan2
- FAM120C | c.1936G>C p.E646Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV60261712; called by muse, mutect2, varscan2
- FBF1 | c.1556G>C p.G519A (on ENST00000586717; = p.G533A on NM_001319193.1) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.958); catalogued as COSV100045072; called by muse, mutect2
- FBN2 | c.4477G>C p.D1493H | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52537317; called by muse, mutect2, varscan2
- FLRT2 | c.167C>G p.S56* | Nonsense Mutation (SNP) | VAF 31/109 reads (28%) | catalogued as COSV100420320; called by muse, mutect2, varscan2
- FPGT | c.1250A>G p.Q417R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.142); catalogued as COSV63845212; called by muse, mutect2, varscan2
- GADL1 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.081); catalogued as COSV56983931; called by muse, mutect2, varscan2
- GFUS | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs780777231, COSV71254354, COSV71254367; called by muse, mutect2, varscan2
- GRIA1 | c.2517G>A p.M839I | Missense Mutation (SNP) | VAF 81/215 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV53619185; called by muse, mutect2, varscan2
- GTF2F1 | c.1325C>T p.S442L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55532723; called by muse, mutect2, varscan2
- H1-2 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs527943061, COSV59191978; called by muse, mutect2, varscan2
- HELLS | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV53300422; called by muse, mutect2, varscan2
- HEXIM2 | c.390G>C p.E130D | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV56237091; called by muse, mutect2, varscan2
- HSPH1 | c.695G>C p.G232A | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60713061; called by muse, mutect2, varscan2
- IL2RG | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.314); catalogued as CD951748, COSV52149675; called by muse, mutect2, varscan2
- IQGAP2 | c.3349G>C p.D1117H | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57179447; called by muse, mutect2, varscan2
- ITGAD | c.811G>T p.V271F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66759555; called by muse, mutect2, varscan2
- KATNBL1 | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.219); catalogued as rs375027107, COSV56625081; called by muse, mutect2
- KCNH3 | c.1954C>T p.R652W | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1233102533, COSV57791866; called by muse, varscan2
- KCTD21 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV60741664; called by muse, mutect2, varscan2
- KIAA1210 | c.608C>G p.S203C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV68179315; called by muse, mutect2, varscan2
- KLHDC2 | c.722G>C p.R241T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV53586867; called by muse, mutect2, varscan2
- KLHL1 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64779793; called by muse, mutect2, varscan2
- KLHL18 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.123); catalogued as COSV51747962; called by muse, mutect2, varscan2
- KPNA1 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as COSV60270941; called by muse, mutect2, varscan2
- KRT77 | c.22C>G p.Q8E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.027); catalogued as COSV59241105; called by muse, mutect2, varscan2
- KRT82 | c.474G>C p.Q158H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as COSV57785725, COSV57786953; called by muse, mutect2, varscan2
- KYAT3 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as COSV53104563; called by muse, mutect2, varscan2
- LIPA | c.686G>C p.G229A | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV51080260; called by muse, mutect2, varscan2
- MACROD2 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54035063; called by muse, mutect2, varscan2
- MAPK15 | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV62029645; called by muse, mutect2, varscan2
- MARVELD3 | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.988); catalogued as COSV51705641; called by muse, mutect2, varscan2
- MED25 | c.758C>G p.S253* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV57206158, COSV57208295; called by muse, mutect2
- MINDY2 | c.1735C>T p.Q579* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as COSV100376385; called by muse, mutect2
- MINDY3 | c.1297G>C p.E433Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53223506, COSV99510596; called by muse, mutect2, varscan2
- MN1 | c.3917C>G p.S1306C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56561109; called by muse, mutect2, varscan2
- MOB1A | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV68517883; called by muse, mutect2
- MS4A1 | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV61942799; called by muse, mutect2, varscan2
- MUSK | c.1572G>A p.W524* | Nonsense Mutation (SNP) | VAF 50/145 reads (34%) | catalogued as COSV51877283; called by muse, mutect2, varscan2
- MYH3 | c.5772G>T p.K1924N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56868875; called by muse, mutect2, varscan2
- MYO15A | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); catalogued as COSV52762947; called by muse, mutect2, varscan2
- MYO15A | c.4587C>G p.F1529L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV52762956; called by muse, mutect2, varscan2
- MYO5C | c.2143G>C p.E715Q | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55910736; called by muse, mutect2, varscan2
- NBEAL1 | c.7302C>G p.I2434M | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs757817387, COSV101355478; called by muse, mutect2
- NCAPH2 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV55371156; called by muse, mutect2, varscan2
- NIPSNAP2 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 120/277 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767257057, COSV59052268; called by muse, mutect2, varscan2
- NSDHL | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0.141); catalogued as rs868918302, COSV64744946; called by muse, mutect2, varscan2
- OR51E2 | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.259); catalogued as COSV67808483; called by muse, mutect2, varscan2
- OR8K3 | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV57132510; called by muse, mutect2, varscan2
- OXSM | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV55002029, COSV55002406; called by muse, mutect2, varscan2
- PHACTR2 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV59855898; called by muse, mutect2, varscan2
- PHC3 | c.1528C>A p.P510T (on ENST00000494943 / NM_001308116.2; = p.P522T on NM_024947.4) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV71949192; called by muse, mutect2, varscan2
- PILRA | c.125C>G p.S42* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV99546463; called by muse, mutect2, varscan2
- PIWIL1 | c.2104G>A p.D702N | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV55344652; called by muse, varscan2
- PKD1L1 | c.4096G>C p.E1366Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV56974713; called by muse, mutect2, varscan2
- PLA2G3 | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.236); catalogued as COSV53211960; called by muse, mutect2, varscan2
- PLK2 | c.745C>G p.P249A | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57109345; called by muse, mutect2, varscan2
- PMS2 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.278); catalogued as COSV56222703; called by muse, mutect2
- POLR1A | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99807490; called by muse, mutect2
- PPP4C | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV54222961; called by muse, mutect2, varscan2
- PTPRM | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1289944484, COSV59880468; called by muse, mutect2
- QSER1 | c.3178G>A p.E1060K (on ENST00000399302; = p.E1189K on NM_001076786.3) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV67901476; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1142C>G p.S381* | Nonsense Mutation (SNP) | VAF 19/77 reads (25%) | catalogued as COSV51480967, COSV99920998; called by muse, mutect2, varscan2
- REV3L | c.4888G>C p.E1630Q | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV62621593; called by muse, mutect2, varscan2
- RFTN2 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.23); catalogued as COSV54385388, COSV54391972; called by muse, mutect2, varscan2
- RIOX2 | c.983C>G p.S328* (on ENST00000333396 / NM_001042533.2; = p.S327* on NM_032778.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | catalogued as COSV99476922; called by muse, mutect2, varscan2
- RNF213 | c.8759C>G p.S2920* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100300420, COSV60407129; called by mutect2, varscan2
- RPS6KA1 | c.220G>C p.G74R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64810334; called by muse, mutect2, varscan2
- RRP1 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV71856918; called by muse, mutect2, varscan2
- RSF1 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV57844300; called by muse, mutect2, varscan2
- SCNN1B | c.324C>G p.I108M | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.214); catalogued as COSV56303721, COSV56308839; called by muse, mutect2, varscan2
- SEC24D | c.1034C>T p.S345L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV54883590; called by muse, mutect2, varscan2
- SEL1L3 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs200984722, COSV53542865; called by muse, mutect2, varscan2
- SERPINE3 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.153); catalogued as COSV68544997, COSV68545747; called by muse, mutect2, varscan2
- SGO2 | c.2674G>A p.D892N | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.801); catalogued as COSV63414478, COSV63417123; called by muse, mutect2, varscan2
- SI | c.3020G>C p.R1007T | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.071); catalogued as COSV52288993, COSV52294901; called by muse, mutect2, varscan2
- SLC5A6 | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV60159189, COSV60160881; called by muse, mutect2, varscan2
- SLC6A16 | c.2059C>T p.P687S | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV60029605, COSV60030379; called by muse, mutect2, varscan2
- SLF2 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1226653549, COSV53278172; called by muse, mutect2, varscan2
- SPTAN1 | c.4159G>A p.E1387K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63989220; called by muse, mutect2, varscan2
- ST13 | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV53423102; called by muse, mutect2, varscan2
- STAMBP | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59897295, COSV59898123; called by muse, mutect2, varscan2
- SUPT3H | c.583G>A p.E195K (on ENST00000371460 / NM_181356.3; = p.E184K on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.969); catalogued as COSV60947756; called by muse, mutect2, varscan2
- SUPT7L | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as rs765547884, COSV61823415; called by muse, mutect2, varscan2
- SYAP1 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs142663946, COSV66467424, COSV66468222; called by muse, mutect2, varscan2
- TAFA2 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs569347374, COSV69175457, COSV69185793; called by muse, mutect2, varscan2
- TANGO6 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.018); catalogued as rs760746324, COSV55761641, COSV55767072, COSV55770968; called by muse, varscan2
- TAPBP | c.413T>G p.L138R | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69668241; called by muse, mutect2, varscan2
- TGM1 | c.1649C>T p.S550L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as CM129979, COSV52864883; called by muse, mutect2, varscan2
- TLK2 | c.1080G>C p.Q360H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV58304655; called by muse, mutect2, varscan2
- TMCO3 | c.7G>A p.V3M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.063); catalogued as rs781417053, COSV60262237; called by muse, mutect2, varscan2
- TMEM132B | c.2077C>G p.Q693E | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as COSV54765480; called by muse, mutect2, varscan2
- TMEM181 | c.862C>A p.Q288K | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV65565370; called by muse, mutect2, varscan2
- TRAK1 | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.089); catalogued as COSV59646564; called by muse, mutect2, varscan2
- TRPV6 | c.342G>C p.Q114H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV63893179; called by muse, mutect2, varscan2
- TSC1 | c.488C>A p.S163* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV100051674; called by muse, mutect2, varscan2
- TTN | c.81451G>C p.D27151H (on ENST00000591111; = p.D19727H on NM_003319.4) | Missense Mutation (SNP) | VAF 13/117 reads (11%) | PolyPhen probably damaging (0.999); catalogued as COSV60267039; called by muse, mutect2, varscan2
- UGT1A8 | c.360T>G p.F120L | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV65084127; called by muse, mutect2
- USP15 | c.1847G>A p.R616Q (on ENST00000280377 / NM_001351159.2; = p.R587Q on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs775355642, COSV54796980; called by muse, varscan2
- WDR59 | c.2386G>A p.D796N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV50941934; called by muse, mutect2, varscan2
- WDR76 | c.305C>G p.S102C | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as COSV51040518; called by muse, mutect2
- WDSUB1 | c.186C>G p.F62L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63068030; called by muse, mutect2, varscan2
- YAP1 | c.956G>A p.R319Q (on ENST00000282441 / NM_001130145.3; = p.R281Q on NM_006106.5) | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.384); catalogued as rs758360525, COSV56776604; called by muse, mutect2
- YLPM1 | c.4428G>A p.M1476I | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV53118468; called by muse, mutect2, varscan2
- ZNF292 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60545028; called by muse, mutect2, varscan2
- ZNF292 | c.8092G>C p.E2698Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs1302008908, COSV60545037; called by muse, mutect2, varscan2
- ZNF483 | c.327G>C p.R109S | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV58515140, COSV58516839; called by muse, mutect2, varscan2
- BRD2 | c.173del p.P58Lfs*28 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- COG6 | c.1746+2dup p.X582_splice | Splice Site (INS) | VAF 18/80 reads (23%) | called by mutect2, pindel, varscan2
- NMT1 | c.1341del p.F447Lfs*23 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- TRAV8-7 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- XBP1 | c.407_431del p.R136Lfs*12 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel
- ZNF84 | c.2078C>T p.S693F | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- ACLY | c.102C>G p.V34= | Silent (SNP) | VAF 9/138 reads (7%) | catalogued as COSV61252414; called by muse, mutect2
- AFDN | c.4809G>A p.A1603= | Silent (SNP) | VAF 41/191 reads (21%) | catalogued as rs374331983; called by muse, mutect2, varscan2
- ALG12 | c.534C>T p.F178= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs139916198; called by muse, mutect2, varscan2
- ANO7 | c.1572C>A p.I524= (on ENST00000274979; = p.I470= on NM_001370694.2) | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV51477228; called by muse, mutect2, varscan2
- APOA1 | c.105G>A p.V35= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV52636631; called by muse, mutect2, varscan2
- ARFGEF2 | c.3411G>C p.V1137= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as COSV64214374; called by muse, mutect2, varscan2
- ARHGEF10L | c.3447C>T p.D1149= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs748841382, COSV99392730; called by muse, varscan2
- ARID1A | c.4578G>A p.V1526= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV61385613; called by muse, mutect2, varscan2
- CCDC114 | c.681C>T p.L227= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as COSV59557280; called by muse, mutect2, varscan2
- CHD7 | c.5226C>T p.V1742= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV101418204; called by muse, mutect2
- CLEC18B | c.372C>T p.V124= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV60578514; called by muse, mutect2
- DCDC2 | c.951G>A p.E317= | Silent (SNP) | VAF 35/239 reads (15%) | catalogued as rs1460623778, COSV65829629; called by muse, mutect2, varscan2
- DDX11 | c.1329G>A p.Q443= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99299510; called by muse, mutect2, varscan2
- EBF2 | c.813C>T p.V271= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV68779983; called by muse, mutect2, varscan2
- EMX2 | c.357C>T p.F119= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV71294797; called by muse, mutect2
- ENDOU | c.363G>A p.E121= (on ENST00000422538 / NM_001172439.2; = p.E80= on NM_006025.4) | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as COSV57465761; called by muse, mutect2, varscan2
- ENPP2 | c.141A>G p.L47= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs976944163, COSV50030089; called by muse, mutect2, varscan2
- FCHSD2 | c.2088C>T p.F696= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV60813471; called by muse, varscan2
- FLNB | c.153C>T p.I51= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV55891500; called by muse, mutect2, varscan2
- FRMD4A | c.2103C>T p.L701= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs534651878, COSV100661743; called by muse, mutect2
- GCDH | c.891C>T p.I297= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs143102910; ClinVar: likely benign; called by muse, mutect2, varscan2
- GTF2F1 | c.258C>T p.I86= | Silent (SNP) | VAF 38/214 reads (18%) | catalogued as rs761360004, COSV66726810; called by muse, mutect2, varscan2
- HCN2 | c.1656C>T p.F552= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs200925272, COSV52117892; called by mutect2, varscan2
- HNRNPCL1 | c.645G>C p.V215= | Silent (SNP) | VAF 51/213 reads (24%) | catalogued as COSV58610500, COSV58614335; called by muse, mutect2, varscan2
- ING5 | c.81G>T p.L27= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV57979641; called by muse, mutect2, varscan2
- LAMB4 | c.4179C>T p.L1393= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV52727911; called by muse, mutect2, varscan2
- MGA | c.4554G>C p.L1518= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV54960802; called by muse, mutect2, varscan2
- NFATC2 | c.1374C>T p.I458= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs1055263764, COSV65359740; called by muse, mutect2, varscan2
- NSMCE3 | c.462C>T p.L154= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99721780; called by muse, mutect2
- OR51B2 | c.528C>T p.F176= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV60916037; called by muse, mutect2, varscan2
- OTOF | c.3075G>C p.L1025= (on ENST00000272371 / NM_194248.3; = p.L278= on NM_004802.4) | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV55514878; called by muse, mutect2, varscan2
- PI4KA | c.651C>A p.L217= | Silent (SNP) | VAF 38/151 reads (25%) | catalogued as COSV55419862; called by muse, mutect2, varscan2
- PLXNA3 | c.1419G>T p.R473= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100859930; called by muse, mutect2, varscan2
- PSME4 | c.2808C>T p.I936= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV66366953; called by muse, mutect2, varscan2
- RARG | c.453C>T p.F151= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as rs775669227, COSV58434278; called by muse, mutect2, varscan2
- RECQL5 | c.1215C>T p.F405= | Silent (SNP) | VAF 222/623 reads (36%) | catalogued as COSV58638753, COSV58645015; called by muse, mutect2, varscan2
- RMDN3 | c.679C>T p.L227= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV53025210, COSV99540184; called by muse, mutect2, varscan2
- SCN1A | c.5007G>A p.A1669= (on ENST00000303395 / NM_001202435.3; = p.A1658= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as rs750366817, COSV57675680; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCNN1B | c.453C>T p.V151= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV56308858; called by muse, mutect2, varscan2
- SLC2A1 | c.1182C>G p.L394= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV65286602, COSV65286697; called by muse, mutect2, varscan2
- SLC2A10 | c.540C>T p.L180= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as COSV63714087; called by muse, mutect2, varscan2
- SLC9C1 | c.1242C>T p.V414= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs1425116561, COSV59891805; called by muse, mutect2
- SOS1 | c.1257C>T p.I419= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV67677152; called by muse, mutect2, varscan2
- SPTAN1 | c.4962G>A p.L1654= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV63988100, COSV63989223; called by muse, varscan2
- SPTAN1 | c.5247C>T p.I1749= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as rs1334875679, COSV63989227; called by muse, mutect2, varscan2
- SPTAN1 | c.5658C>A p.I1886= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV63989230; called by muse, mutect2, varscan2
- SRRM2 | c.213C>G p.L71= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV57079085; called by muse, mutect2, varscan2
- SYP | c.846C>A p.A282= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV99602836; called by muse, mutect2
- TAX1BP1 | c.174T>C p.S58= | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as rs1254449895, COSV55295978; called by muse, mutect2, varscan2
- TMEM214 | c.1353G>A p.L451= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV53192133, COSV53193643; called by muse, mutect2, varscan2
- UBE4B | c.2574G>A p.L858= (on ENST00000343090 / NM_001105562.3; = p.L729= on NM_006048.5) | Silent (SNP) | VAF 56/181 reads (31%) | catalogued as COSV53539797; called by muse, mutect2, varscan2
- ZNF12 | c.1200G>A p.Q400= (on ENST00000405858 / NM_016265.4; = p.Q362= on NM_006956.3) | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs541433447, COSV61245317; called by muse, mutect2, varscan2
- ARHGEF11 | c.583-1681G>C | Intron (SNP) | VAF 28/104 reads (27%) | catalogued as COSV63815043; called by muse, mutect2, varscan2
- GPR68 | c.-11C>G | 5'UTR (SNP) | VAF 14/45 reads (31%) | catalogued as COSV99473442; called by muse, mutect2, varscan2
- NFASC | c.2471-1422C>T | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100363637; called by muse, mutect2
- NIN | chr14:50723507 G>A | 3'Flank (SNP) | VAF 29/61 reads (48%) | catalogued as COSV55402470; called by muse, mutect2, varscan2
- ZNF626 | c.226+259G>A | Intron (SNP) | VAF 14/44 reads (32%) | catalogued as rs917328212, COSV52482420; called by muse, mutect2, varscan2
